Somatic mutation profile of tumor specimen ALCH-AFFY-TTP1-A (aliquot ALCH-AFFY-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-AFFY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,149 days).
Specimen ALCH-AFFY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c212dc9d-a7db-4448-a299-89c319d20c15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFY-NB1-A (Blood Derived Normal), aliquot ALCH-AFFY-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0feeb96-d367-4fbb-9d6a-7a9e76080e7e

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 6, 5'UTR 2, Nonstop Mutation 1, Splice Site 1, Intron 1, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 113/504 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 96/477 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1838T>A p.I613N | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as CM021056; called by muse, mutect2
- CRB1 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66332235, COSV66332501; called by muse, mutect2, varscan2
- CSF2RA | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 74/512 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV62624315; called by muse, mutect2, varscan2
- DST | c.10490C>T p.T3497M | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751132203, COSV55000624; called by muse, mutect2, varscan2
- GCNA | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 87/443 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs761879832, COSV65468375; called by muse, mutect2, varscan2
- HPSE | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1352411785; called by muse, mutect2, varscan2
- PELO | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1209395373; called by muse, mutect2
- TPTE2 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.429); catalogued as COSV55021935, COSV99689926; called by muse, mutect2, varscan2
- WNK4 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 55/282 reads (20%) | catalogued as COSV53821945; called by muse, mutect2, varscan2
- ZNF684 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs1444988261, COSV101016109; called by muse, mutect2, varscan2
- ZSCAN10 | c.1141G>C p.E381Q (on ENST00000252463; = p.E436Q on NM_032805.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV52969607; called by muse, mutect2, varscan2
- AK9 | c.5316-2A>G p.X1772_splice | Splice Site (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- ATN1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2
- FAM81B | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HTRA1 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLHDC7A | c.649A>T p.S217C | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- LZTFL1 | c.898T>C p.*300Qext*2 | Nonstop Mutation (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- NAA38 | c.100G>A p.E34K (on ENST00000575771 / NM_001320925.2; = p.E82K on NM_032356.5) | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- OR8H1 | c.823G>T p.V275F | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHIP | c.3045A>C p.L1015F | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SMAD4 | c.598_599dup p.L201Cfs*2 | Frame Shift Ins (INS) | VAF 82/348 reads (24%) | called by mutect2, pindel, varscan2
- TM9SF4 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TNS4 | c.1844C>G p.P615R | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSC1 | c.1263G>A p.K421= | Splice Region (SNP) | VAF 47/173 reads (27%) | called by muse, mutect2, varscan2
- ZNF257 | c.1469A>T p.E490V | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ZNF365 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ZNF684 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ZNFX1 | c.1623_1624del p.H542Cfs*41 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by pindel, varscan2
- BCORL1 | c.5079G>A p.E1693= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- KCNK17 | c.597C>G p.L199= | Silent (SNP) | VAF 38/232 reads (16%) | called by muse, mutect2, varscan2
- TSPAN33 | c.264C>T p.R88= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as rs142963022, COSV56825672; called by muse, mutect2, varscan2
- USP11 | c.2034C>T p.D678= (on ENST00000218348; = p.D635= on NM_001371072.1) | Silent (SNP) | VAF 30/173 reads (17%) | called by muse, mutect2, varscan2
- YDJC | c.198G>C p.L66= | Silent (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- ZNF684 | c.1056G>A p.E352= | Silent (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- DIP2B | c.-51_-44del | 5'UTR (DEL) | VAF 23/177 reads (13%) | called by mutect2, pindel, varscan2
- FAM20C | c.864-24_864-22del | Intron (DEL) | VAF 32/242 reads (13%) | called by mutect2, pindel, varscan2
- LINC00269 | n.659C>T | RNA (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- MFSD5 | chr12:53251962 C>G | 5'Flank (SNP) | VAF 55/225 reads (24%) | catalogued as rs1173112402; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827908 C>G | 3'Flank (SNP) | VAF 16/330 reads (5%) | catalogued as COSV100158207; called by muse, mutect2
- TRAV27 | c.-1G>C | 5'UTR (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- ZNF99 | c.*2866C>A | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
